Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A4LC, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A4LC-01A (Primary Tumor).

[page 1 of 4]
Result type: Report
Result date:
Result status: Auth (Verified)
Result title: SPECIMEN DESCRIPTION
Performed by:

*** Final Report ***

SPECIMEN DESCRIPTION

LEVEL NO 7 LYMPH NODE
TUMOR RIGHT LUNG
RIGHT LUNG
LEVEL NO 8 LYMPH NODE
LEVEL NO 9 LYMPH NODE
DIAPHRAGMATIC TUMOR
LEVEL NO 4 LYMPH NODE
6TH RIGHT RIB FOR

1CD-0-3

Mesothelioma, epithelioid, NOS 9052/3

Site: pleura, NOS C38.4

*hw
10/4/12*

SURGICAL PATHOLOGY REPORT

LOCATION:

PATHOLOGY NO.:

HOSPITAL ID:

HOSPITAL NO.:
ACCOUNT NO.:
DATE RECEIVED:
DATE OF PROCEDURE:
ACCN REQ. NO.: NOT GIVEN

PATIENT'S NAME:
AGE/SEX/DOB: M
PHYSICIAN(S):
COPY TO:

DIAGNOSIS:

A. LEVEL VII LYMPH NODE, EXCISION:
ELEVEN LYMPH NODES NEGATIVE FOR MALIGNANCY.

B. RIGHT LUNG, TUMOR EXCISION:
MALIGNANT MESOTHELIOMA, TUBULOPAPILLARY TYPE.

C. RIGHT LUNG, EXTRAPLEURAL PNEUMONECTOMY:
MALIGNANT MESOTHELIOMA, EPITHELIAL, TUBULOPAPILLARY TYPE, DIFFUSE.
BRONCHIAL MARGIN NEGATIVE FOR TUMOR.
LUNG PARENCHYMA FREE OF TUMOR.
NINE HILAR LYMPH NODES NEGATIVE FOR MALIGNANCY.

D. LEVEL VIII LYMPH NODE, EXCISION:
THREE LYMPH NODES NEGATIVE FOR MALIGNANCY.

E. LEVEL IX LYMPH NODE, EXCISION:
ONE LYMPH NODE NEGATIVE FOR MALIGNANCY.

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
F. LABELED DIAPHRAGMATIC TUMOR:

MALIGNANT MESOTHELIOMA, EPITHELIAL, TUBULOPAPILLARY TYPE, INVADING FIBROCOLLAGENOUS TISSUE AND FOCALLY THE SKELETAL MUSCLE.

G. LEVEL IV LYMPH NODE, EXCISION:

FOUR LYMPH NODES NEGATIVE FOR MALIGNANCY.

H. RIB, RESECTION:

FOR GROSS ONLY.

COMMENT: The tumor present in specimens B, C and F is formed by epithelial cells with eosinophilic cytoplasm, round nucleus and prominent nucleoli. These cells are arranged in glands and form papilla as well as nests. The immunohistochemical studies confirm the diagnosis of malignant mesothelioma: the tumor cells are positive for calretinin, thrombomodulin, WT-1, cytokeratin and negative for B72.3, CEA, and BERP-4.

=====

SPECIMEN: A LEVEL NO 7 LYMPH NODE
B TUMOR RIGHT LUNG
C RIGHT LUNG
D LEVEL NO 8 LYMPH NODE
E LEVEL NO 9 LYMPH NODE
F DIAPHRAGMATIC TUMOR
G LEVEL NO 4 LYMPH NODE
H 6TH RIGHT RIB FOR
OPERATION: R EXTRAPLEURAL PNEUMONECTOMY
PRE-OP DIAGNOSIS: LUNG CANCER RT
POST-OP DIAGNOSIS: SAME
CLINICAL DATA: NOT GIVEN

GROSS DESCRIPTION: The specimen is received in eight separate containers.

A. Received fresh labeled level 7 lymph node is one fragment of fibroadipose tissue measuring 5.5 x 2.0 x 0.5 cm.

Summary of sections:

- 1- one lymph node bisected,
- 2- two possible lymph nodes,
- 3- one lymph node bisected,
- 4- two lymph nodes bisected,
- 5- one lymph node bisected,
- 6- one lymph node bisected,
- 7- one lymph node,
- 8- one lymph node bisected.

B. Received fresh labeled tumor right lung is one fragment of fibroadipose tissue measuring 2.0 x 1.0 x 0.2 cm. Entirely submitted in two cassettes.

Printed by: [REDACTED]
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
[REDACTED]

C. Received fresh labeled right lung is a right extrapleural pneumonectomy specimen measuring 20.0 x 15.0 x 4.0 cm. weighing 800 gm. total. The parietal pleura is attached at the superior part of the specimen and measures 30 x 15 cm, with 0.2 cm thickness. The thoracic, diaphragmatic, and mediastinal surface of the lung is almost entirely covered by granular, tan indurated nodules. The lung is serially sectioned. The lung's parenchyma is soft, red, and free of tumor, except at the mediastinal aspect of the lung where the tumor appears to invade the lung parenchyma. The parietal pleura also shows multiple nodules, the largest measuring 10 x 3 x 3 cm and appears to invade the lung.

Summary of sections:

1&2-sections from the tumor,
3-bronchial margin with two lymph nodes,
4-vessels with one hilar lymph node,
5-three possible lymph nodes,
6 -three possible lymph nodes,
7-tumor to lung parenchyma,
8&9-tumor and parietal pleura.
10-tumor.

D. Received fresh labeled level 8 lymph node is a piece of tissue measuring 1.5 x 0.8 x 0.3 cm. Two lymph nodes are identified measuring 0.5 and 0.7 cm.

Summary of sections:

D1- one lymph node bisected,
D2- one lymph node bisected.

E. Received fresh labeled level 9 lymph node is one lymph node measuring 1.0 x 0.5 x 0.2 cm. The specimen is bisected and entirely submitted in one cassette.

F. Received fresh labeled tumor diaphragmatic are multiple fragments of fibroadipose tissue with fibrous white granular tissue aggregating to 5.0 x 5.0 x 1.0 cm. Representative sections are submitted in two cassettes.

G. Received fresh are two anthracotic lymph nodes measuring 1.2 and 0.5 cm.

Summary of cassettes:

1- one lymph node bisected,
2- one lymph node.

H. Received fresh labeled ribs are six fragments of bone submitted for Dr. study.

CPT CODE:

Printed by: [REDACTED]
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
ELECTRONIC SIGNATURE: [REDACTED]

Completed Action List:

* Perform by

Printed by:
Printed on:

Page 4 of 4
(End of Report)

4/23/12

Source: NCI Genomic Data Commons file 236dd483-b807-4c1e-9a7e-981e7f1e47da (TCGA-MQ-A4LC.731F15DB-25D3-41A5-AEA5-4C96F1249ABA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).